Somatic mutation profile of tumor specimen TCGA-CV-5979-01A (aliquot TCGA-CV-5979-01A-11D-1683-08) from TCGA case TCGA-CV-5979, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 26.2 years (9,567 days).
Specimen TCGA-CV-5979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 128573fb-1105-46ce-87c8-aea6c5df6b4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5979-11A (Solid Tissue Normal), aliquot TCGA-CV-5979-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b905f56-ed3d-4a3c-8ae1-bf25f51ab3df

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASPM | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54130204; called by muse, mutect2, varscan2
- CDC42EP4 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.588); catalogued as COSV100231753; called by muse, mutect2, varscan2
- CLDN18 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV51736049; called by muse, mutect2, varscan2
- DOCK3 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV56522566; called by muse, mutect2, varscan2
- FAM135B | c.1859A>T p.K620M | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52726346; called by muse, mutect2, varscan2
- FGB | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV57417482; called by muse, mutect2, varscan2
- IL3RA | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs764345006, COSV100452184; called by muse, mutect2, varscan2
- KNDC1 | c.4394C>T p.T1465M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as rs540301676, COSV58832829; called by muse, mutect2, varscan2
- KRTAP10-9 | c.574T>A p.C192S | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100552014; called by muse, mutect2
- MAP1A | c.7843C>A p.P2615T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as COSV55809042; called by muse, mutect2, varscan2
- MRPL17 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV99996779; called by muse, mutect2
- NOS1AP | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1001048433, COSV62632789; called by muse, mutect2, varscan2
- PFKP | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV56527650; called by muse, mutect2, varscan2
- RFX4 | c.1156C>A p.H386N (on ENST00000392842 / NM_213594.3; = p.H292N on NM_032491.6) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV57573282; called by muse, mutect2, varscan2
- RNF213 | c.10306C>A p.L3436M | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as COSV100299770; called by muse, mutect2
- SGK2 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV58312398; called by muse, mutect2, varscan2
- SHPRH | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.61); catalogued as rs773082076, COSV51610439; called by muse, mutect2, varscan2
- TEX9 | c.138G>T p.L46F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61878303; called by muse, mutect2, varscan2
- TNFRSF6B | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1489149878, COSV99422746; called by muse, mutect2
- XIRP2 | c.7205A>G p.N2402S (on ENST00000628543; = p.N2577S on NM_152381.6) | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54701713; called by muse, mutect2, varscan2
- ZCCHC14 | c.1986A>C p.Q662H (on ENST00000268616; = p.Q799H on NM_015144.3) | Missense Mutation (SNP) | VAF 139/231 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51884640; called by muse, mutect2, varscan2
- ZNF414 | c.641A>T p.D214V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV55321241, COSV99726455; called by muse, mutect2
- OR4Q3 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCNT2 | c.474G>A p.S158= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs754150475, COSV101097552, COSV65457353; called by muse, mutect2, varscan2
- KRT14 | c.804C>A p.V268= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV51421385; called by muse, mutect2, varscan2
- ODF3 | c.396A>G p.R132= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57293827; called by muse, mutect2, varscan2
- PIGC | c.727C>T p.L243= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV51129967; called by muse, mutect2, varscan2
- REXO1 | c.2826C>T p.N942= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs138422554; called by muse, mutect2, varscan2
- TCF7L2 | c.1398G>A p.A466= (on ENST00000355995 / NM_001367943.1; = p.A443= on NM_030756.5) | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs373202228; called by muse, mutect2, varscan2
